Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A1AD, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A1AD-01A (Primary Tumor).

[page 1 of 4]
106-0-3

Carcinoma, urothelial, NOS 8120/3

12/30/10

Site Code: bladder, NOS 667.9

SURGICAL PATHOLOGY REPORT**Patient Name:****Med. Rec. #:**

DOB:

Gender:

M

Ref. Physician:

Patient Address:

Location:

Service:

Urology

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

INPATIENT

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

male with invasive bladder cancer, for cystectomy.

Specimens Submitted:

- 1: SP: Bladder, prostate, seminal vesicles, urachus, perivesical nodes, urethra (
- 2: SP: Rt. vas deferens (
- 3: SP: Lt. vas deferens (
- 4: SP: Lt. pelvic lymph nodes (
- 5: SP: Rt. pelvic lymph nodes (
- 6: SP: Rt. hypogastric lymph nodes (
- 7: SP: Lt. distal ureter (
- 8: SP: Rt. distal ureter (

DIAGNOSIS:

- 1) PROSTATE, SEMINAL VESICLES, URACHUS, PERIVESICAL NODES AND URETHRA; RESECTION:
- INVASIVE UROTHELIAL CARCINOMA, HIGH GRADE, SPANS 4.0 CM IN GREATEST DIMENSION.
- INVASIVE CARCINOMA SHOWS FOCAL GLANDULAR FEATURES.
- THE PATTERN OF GROWTH IS NODULAR.
- THE TUMOR INVADIES INTO THE PERIVESICAL SOFT TISSUES (pT3b).
- EXTENSIVE IN-SITU CARCINOMA IS ALSO PRESENT.
- CARCINOMA IN-SITU EXTENDS ALONG THE PROSTATIC URETHRA.
- NO VASCULAR INVASION IS IDENTIFIED.
- PERINEURIAL INVASION IS PRESENT.
- EXAMINED SURGICAL MARGINS ARE FREE OF CARCINOMA (SEE ALSO PART #8).
- THE NON-NEOPLASTIC MUCOSA SHOWS CHRONIC CYSTITIS.
- THE PROSTATE SHOWS NODULAR HYPERPLASIA AND FOCAL HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN).
- THE SEMINAL VESICLES ARE UNREMARKABLE.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): PERIVESICAL LYMPH NODES-THREE BENIGN LYMPH NODES (0/3).
- 2) RIGHT VAS DEFERENS; BIOPSY:
- BENIGN VAS DEFERENS.
- 3) LEFT VAS DEFERENS; BIOPSY:
- BENIGN FIBROMUSCULAR AND VASCULAR TISSUE.
- 4) LYMPH NODE, LEFT PELVIC; EXCISION:
- BENIGN ADIPOSE AND VASCULAR TISSUE.
- 5) LYMPH NODES, RIGHT PELVIC; EXCISION:
- METASTATIC UROTHELIAL CARCINOMA IN ONE OF SEVEN LYMPH NODES (1/7).
- 6) LYMPH NODES, RIGHT HYPOGASTRIC; EXCISION:
- METASTATIC UROTHELIAL CARCINOMA IN ONE OF FOUR LYMPH NODES (1/4).

Case in Circle		

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

- 7) DISTAL URETER, LEFT; BIOPSY:
- BENIGN URETER. THERE IS NO EVIDENCE OF MALIGNANCY.
- 8) DISTAL URETER, RIGHT; BIOPSY:
- BENIGN URETER. THERE IS NO EVIDENCE OF MALIGNANCY.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result Spec	al Stain	Comment
RECUT		

Gross Description:

1) The specimen is received fresh, labeled "Bladder, prostate, seminal vesicles, urachus, perivesical nodes, urethra". It consists of a 6.0 x 5.5 x 4.7 cm bladder with a 4.5 x 3.5 x 2.0 cm attached prostate. The specimen is opened anteriorly to reveal a 4.0 x 3.0 x 2.5 cm tan-white, infiltrative tumor, present in the right-inferior aspect of the bladder. The surface of the lesion is ulcerated. The lesion is 1.8 cm from the urethral resection margin. Additionally, there is a 1.2 x 1.0 cm ulcerated area present in the junction of bladder and urethral mucosa. The mucosal surface of the dome, left aspect of the bladder is grossly without lesions. The perivesical adipose tissue is grossly unremarkable. The left ureter is opened to reveal tan-pink, smooth mucosal surfaces. The right side ureter is possibly obliterated by the tumor and is grossly not identified. The prostate is cut to reveal tan, soft cut surfaces. No additional tumor is grossly seen. Multiple possible lymph nodes are identified in the perivesical adipose tissue. The specimen is photographed and TPS is sampled. Representative sections are submitted.

The prostate weighs 68 grams. The prostate measures 3.8 cm from apex to base, 4.0 cm transversely, and 3.2 cm from anterior to posterior. The right and left seminal vesicles measure 4.0 x 2.3 cm and 4.0 x 2.0 cm, respectively. The external surface of the prostate is smooth. The prostate is inked (right - green; left - blue) and fixed in formalin overnight. The prostate is serially sectioned from apex to base at approximately 3 mm intervals. The prostate is entirely submitted.

Summary of Sections:

UR - urethral area
LUR - left ureter
TUR - tumor to urethra
T - tumor
B - random sections of bladder
RA - right apical margin
LA - left apical margin
BN - bladder neck margin
RSV- right seminal vesicle
LSV - left seminal vesicle
A-G - serial sections of prostate (apex to base)
PLN - Possible lymph nodes

- 2) The specimen is received in formalin, labeled "Right vas deferens". It consists of a tubular shaped fragment of vas deferens surrounded by adipose tissue, measuring 3 cm in length and 0.3 cm in diameter. Representative sections are submitted.

Summary of sections:

U - undesignated

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

3) The specimen is received in formalin, labeled "Left vas deferens". It consists of a tubular shaped fragment of vas deferens measuring 3 cm in length and 0.3 cm in diameter. Representative sections are submitted.

Summary of sections:

U - undesignated

4) The specimen is received in formalin, labeled "Left pelvic lymph nodes". It consists of multiple fragments of adipose tissue measuring in aggregate 3 x 2 x 0.6 cm. Entirely submitted for all of the possible lymph nodes.

Summary of sections:

U - undesignated

5) The specimen is received in formalin, labeled "Right pelvic lymph nodes". It consists of multiple pieces of adipose tissue measuring in aggregate 6 x 4 x 1 cm. Multiple lymph nodes are identified ranging from 0.5 up to 2 cm in greatest dimension. The largest lymph node is bisected. The nodes are entirely submitted.

Summary of sections:

LN - lymph nodes

6) The specimen is received in formalin, labeled "Right hypogastric lymph nodes". It consists of two lymph nodes ranging from 1 up to 1.5 cm in greatest dimension. The nodes are entirely submitted.

Summary of sections:

LN - lymph nodes

7) The specimen is received in formalin, labeled "Left distal ureter". It consists of a fragment of unremarkable ureter surrounded by adipose tissue. The ureter measures 1.5 cm in length and 0.2 cm in diameter. Representative sections are submitted.

Summary of sections:

LU - left ureter

8) The specimen is received in formalin, labeled "Right distal ureter". It consists of a fragment of unremarkable ureter surrounded by adipose tissue. The ureter measures 2 cm in length and 0.3 cm in diameter. Representative sections are submitted.

Summary of sections:

RU - right ureter

Summary of Sections:

Part 1: SP: Bladder, prostate, seminal vesicles, urachus, perivesical nodes, urethra (am)

Block	Sect. Site	PCs
1	A	1
3	B	3
1	BN	1
1	C	1
1	D	1
1	E	1
1	F	1
1	G	1
1	LA	1
1	LSV	1
1	LUR	1

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

5	PLN	5
1	RA	1
1	RSV	1
5	T	5
1	TUR	1
1	UR	1

Part 2: SP: Rt. vas deferens (pjm)

Block	Sect. Site	PCs
1	U	3

Part 3: SP: Lt. vas deferens (pjm)

Block	Sect. Site	PCs
1	U	3

Part 4: SP: Lt. pelvic lymph nodes (pjm)

Block	Sect. Site	PCs
2	U	4

Part 5: SP: Rt. pelvic lymph nodes (pjm)

Block	Sect. Site	PCs
2	BLN	2
1	LN	3

Part 6: SP: Rt. hypogastric lymph nodes (pjm)

Block	Sect. Site	PCs
1	LN	3

Part 7: SP: Lt. distal ureter (pjm)

Block	Sect. Site	PCs
1	LU	3

Part 8: SP: Rt. distal ureter (pjm)

Block	Sect. Site	PCs
1	RU	3

Source: NCI Genomic Data Commons file b7419cad-18af-4621-98c3-76ddd653f8bf (TCGA-DK-A1AD.E4D38398-CB3D-431A-8A1A-192565082A98.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).